Somatic mutation profile of tumor specimen 0DNKZH from CCDI case PBCBGG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.1 years (3,313 days).
Specimen 0DNKZH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6de4c1ca-3009-4833-9126-1d80bdd903dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNKZB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fab79aa-21db-412e-9019-460cfc116d64

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL11A | c.1129G>A p.D377N (on ENST00000335712 / NM_001365609.1; = p.D411N on NM_018014.4) | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100186751; called by muse, mutect2, varscan2
- IZUMO1R | c.577C>T p.R193* (on ENST00000440961; = p.R200* on NM_001199206.3) | Nonsense Mutation (SNP) | VAF 86/530 reads (16%) | catalogued as rs753916969, COSV60622696; called by muse, mutect2, varscan2
- RIMS1 | c.3430C>T p.R1144* | Nonsense Mutation (SNP) | VAF 24/326 reads (7%) | catalogued as rs202076893, CM140475; called by muse, mutect2
- TRAF2 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs369480645; called by muse, mutect2, varscan2
- GTF2H2C | c.122C>A p.A41E | Missense Mutation (SNP) | VAF 94/348 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- SALL3 | c.3344G>T p.C1115F | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2
- JAKMIP2 | c.627+17C>T | Intron (SNP) | VAF 81/180 reads (45%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23875C>T | Intron (SNP) | VAF 69/631 reads (11%) | catalogued as rs762054564; called by muse, mutect2
